Somatic mutation profile of tumor specimen TCGA-ET-A3DQ-01A (aliquot TCGA-ET-A3DQ-01A-11D-A19J-08) from TCGA case TCGA-ET-A3DQ, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary carcinoma, follicular variant; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 43.5 years (15,871 days).
Specimen TCGA-ET-A3DQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1d09b28e-d075-4b27-be51-cb9007f218c3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ET-A3DQ-10A (Blood Derived Normal), aliquot TCGA-ET-A3DQ-10A-01D-A19M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1e6411f7-cfd4-4b51-ace5-1fa26a5a59b9

The open-access MAF lists 4 somatic variants for this specimen: 2 protein-altering or splice-affecting, 2 silent.
By variant classification: Silent 2, Missense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KLHL14 | c.100G>T p.D34Y | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); catalogued as COSV63830400; called by muse, mutect2, varscan2
- ZDHHC8 | c.1397C>T p.A466V | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.334); catalogued as rs865985986, COSV100273123; called by muse, mutect2
- CASP7 | c.312G>T p.L104= | Silent (SNP) | VAF 24/153 reads (16%) | catalogued as COSV61880882; called by muse, mutect2, varscan2
- CITED2 | c.627C>A p.P209= | Silent (SNP) | VAF 13/103 reads (13%) | catalogued as COSV62726178; called by muse, mutect2, varscan2
